CCDI case PBBNWE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/70555e5b-bc5b-4571-b745-84d8c04cc767

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander; Vital status: Alive.

Diagnoses (1)
1. Neurofibromatosis, NOS: ICD-O-3 morphology code: 9540/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,130 days).

Biospecimens (3 samples)
- Sample 0DDNCM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDNCN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDNCO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
